Somatic mutation profile of tumor specimen MBCProject_5971_T2_WES (aliquot MBCProject_5971_T2_WES_1) from CMI case MBCProject_5971, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.6 years (19,572 days).
Specimen MBCProject_5971_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0460b995-7974-4dcd-9db4-2a42c89e5847.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5971_SALIVA (Saliva), aliquot MBCProject_5971_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c9542b3-d876-4696-8c74-6d50cf6b53f6

The open-access MAF lists 110 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Intron 9, RNA 7, Splice Site 4, Nonsense Mutation 3, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2, Splice Region 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs745463398; called by muse, mutect2, varscan2
- BBS9 | c.1856G>A p.R619H (on ENST00000242067 / NM_001348036.1; = p.R579H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750412402; called by muse, mutect2, varscan2
- BCL9 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV52347151; called by muse, mutect2
- CACNA1S | c.901-1G>C p.X301_splice | Splice Site (SNP) | VAF 36/327 reads (11%) | catalogued as rs753395334; called by muse, mutect2, varscan2
- CFAP206 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1210142360; called by muse, mutect2
- CNOT9 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV55298896; called by muse, mutect2, varscan2
- FAT1 | c.6610G>A p.V2204M | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs750302176, COSV101498864; called by muse, mutect2, varscan2
- GLT1D1 | c.730G>A p.A244T (on ENST00000442111 / NM_001366889.1; = p.A164T on NM_144669.3) | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs759619312, COSV55878029; called by muse, mutect2, varscan2
- GRIK2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs755777802, COSV59784426; called by muse, mutect2, varscan2
- JAK3 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV71687488; called by muse, mutect2
- LRP2 | c.13847C>T p.S4616L | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs140802648; called by muse, varscan2
- LRP2 | c.13676C>T p.S4559F | Missense Mutation (SNP) | VAF 79/528 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99787814; called by muse, mutect2, varscan2
- MS4A10 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100382287; called by muse, mutect2, varscan2
- NBEA | c.1392G>C p.E464D | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100084839, COSV59790289; called by muse, mutect2, varscan2
- PIP4K2C | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 31/446 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs753747468; called by muse, mutect2
- POTEC | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs149536586, COSV100743692, COSV62804206; called by muse, varscan2
- PVRIG | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1199071982; called by muse, mutect2
- PXDNL | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1263812907, COSV62485776; called by muse, mutect2, varscan2
- RNF34 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782463794; called by muse, mutect2
- SLC9A3 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99375852; called by muse, mutect2, varscan2
- SOWAHD | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.215); catalogued as COSV100673101; called by muse, mutect2, varscan2
- SYNE1 | c.15581G>A p.R5194H (on ENST00000367255 / NM_182961.4; = p.R5123H on NM_033071.3) | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751121212, COSV54940830; called by muse, mutect2, varscan2
- USP34 | c.6419C>G p.S2140* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV101276996; called by muse, mutect2, varscan2
- VARS2 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs756388943, COSV58912691; called by muse, mutect2, varscan2
- ABCD2 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- AKAP9 | c.10543A>G p.K3515E (on ENST00000359028; = p.K3491E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ALPG | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP7A | c.2791C>T p.Q931* | Nonsense Mutation (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- BAG4 | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- BPNT1 | c.765A>T p.L255F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BTN2A1 | c.972C>G p.F324L | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- C22orf42 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.068); called by muse, mutect2
- CAND1 | c.1817C>A p.S606Y | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CNTLN | c.2411G>A p.R804K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRTC2 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSTF1 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 53/555 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2
- DCAF8 | c.1678-4_1699del p.X560_splice | Splice Site (DEL) | VAF 46/266 reads (17%) | called by mutect2, pindel
- DCC | c.1084G>C p.V362L | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, varscan2
- DDX53 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DZIP3 | c.2324C>A p.T775N | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, varscan2
- FANCG | c.1480+6C>G | Splice Region (SNP) | VAF 85/449 reads (19%) | called by muse, mutect2, varscan2
- FUT11 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABRB3 | c.1217G>T p.S406I | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GC | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, varscan2
- GRAMD1C | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 44/599 reads (7%) | called by muse, mutect2
- H3C6 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- HMCN1 | c.15649T>A p.C5217S | Missense Mutation (SNP) | VAF 37/387 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL21 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IPO8 | c.3004C>G p.R1002G | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, varscan2
- IRF8 | c.1253dup p.R419Qfs*51 | Frame Shift Ins (INS) | VAF 51/470 reads (11%) | called by mutect2, pindel, varscan2
- LARS1 | c.2072C>T p.A691V (on ENST00000394434 / NM_020117.11; = p.A664V on NM_016460.3) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LTBP1 | c.3137A>G p.N1046S (on ENST00000404816 / NM_206943.4; = p.N720S on NM_000627.4) | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, varscan2
- MAST1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MEGF8 | c.4862C>T p.A1621V (on ENST00000251268 / NM_001271938.2; = p.A1554V on NM_001410.3) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8B4 | c.581G>C p.S194T | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- PTPRQ | c.2117-1G>A p.X706_splice (on ENST00000616559; = p.X664_splice on NM_001145026.2) | Splice Site (SNP) | VAF 37/318 reads (12%) | called by muse, mutect2, varscan2
- RBM39 | c.417-1G>C p.X139_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- RNF17 | c.3907T>C p.W1303R | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RUNX1 | c.285_286dup p.D96Gfs*11 (on ENST00000344691 / NM_001001890.3; = p.D123Gfs*11 on NM_001754.5) | Frame Shift Ins (INS) | VAF 65/566 reads (11%) | called by mutect2, pindel, varscan2
- SLC6A8 | c.1510A>T p.M504L | Missense Mutation (SNP) | VAF 57/459 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMTN | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- TEX35 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TLL2 | c.1906T>G p.W636G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TOMM40 | c.1067T>G p.F356C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- TRIM29 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- USP4 | c.902T>G p.L301R | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZFYVE26 | c.7106T>C p.M2369T | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ZNF423 | c.2225C>T p.S742F (on ENST00000563137 / NM_001379286.1; = p.S734F on NM_015069.4) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALG8 | c.1200A>C p.A400= | Silent (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- CDKN2D | c.411C>A p.A137= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- CGNL1 | c.2001A>G p.T667= | Silent (SNP) | VAF 47/229 reads (21%) | catalogued as rs1442214089; called by muse, mutect2, varscan2
- CHMP1A | c.135C>T p.A45= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as COSV99498292; called by muse, mutect2, varscan2
- D2HGDH | c.252G>A p.A84= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as rs1267993351; called by muse, mutect2, varscan2
- GATA2 | c.111G>A p.A37= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs1314011259; called by muse, mutect2
- GHSR | c.564C>T p.N188= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as rs752005705, COSV53838092; called by muse, mutect2, varscan2
- GTF3C1 | c.4386C>T p.H1462= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs771717375; called by muse, mutect2, varscan2
- HOOK2 | c.2043G>A p.E681= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs1488405324; called by muse, mutect2, varscan2
- HPGDS | c.561C>T p.V187= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs768212908; called by muse, mutect2, varscan2
- LRP1B | c.12540A>T p.A4180= | Silent (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- NLRC5 | c.108C>A p.L36= | Silent (SNP) | VAF 32/380 reads (8%) | called by muse, mutect2
- NXN | c.798C>G p.L266= | Silent (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- OTOGL | c.5790T>C p.C1930= (on ENST00000547103; = p.C1921= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1965C>T p.T655= | Silent (SNP) | VAF 45/408 reads (11%) | catalogued as COSV53379369; called by muse, mutect2, varscan2
- RNF25 | c.351C>G p.L117= | Silent (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- RXRG | c.1065T>C p.V355= | Silent (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- SLC12A3 | c.810G>A p.V270= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs1212376105; called by muse, mutect2, varscan2
- ZNF346 | c.42C>T p.G14= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1252514269; called by muse, mutect2, varscan2
- ZSCAN32 | c.210C>T p.H70= (on ENST00000396846; = p.H71= on NM_001284527.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs553651109; called by muse, mutect2
- AC011525.1 | n.956G>A | RNA (SNP) | VAF 15/230 reads (7%) | catalogued as rs1421796772; called by muse, mutect2
- AC022148.1 | n.225C>T | RNA (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- AC134312.1 | n.496C>T | RNA (SNP) | VAF 3/19 reads (16%) | catalogued as rs1480665030; called by muse, mutect2
- ACTG1 | c.*633A>C | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, varscan2
- AL353804.7 | chrX:73847182 G>A | 5'Flank (SNP) | VAF 52/401 reads (13%) | called by muse, mutect2, varscan2
- ASPH | c.416-13G>A | Intron (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- CYBA | c.369+821C>T | Intron (SNP) | VAF 38/281 reads (14%) | called by muse, mutect2, varscan2
- DDX39B | c.340-20C>G | Intron (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- EPHB2 | c.967+16C>T | Intron (SNP) | VAF 34/446 reads (8%) | called by muse, mutect2
- FAM104B | c.20+197C>T | Intron (SNP) | VAF 55/349 reads (16%) | called by muse, mutect2, varscan2
- FAM183BP | n.872G>A | RNA (SNP) | VAF 21/277 reads (8%) | catalogued as rs759720696; called by muse, mutect2
- FAM27E5 | n.179C>T | RNA (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- HYPK | c.-27C>T | 5'UTR (SNP) | VAF 43/317 reads (14%) | catalogued as rs754881698; called by muse, mutect2, varscan2
- MIR365B | chr17:31575608 A>G | 3'Flank (SNP) | VAF 10/61 reads (16%) | called by muse, varscan2
- MMADHC | c.-14C>T | 5'UTR (SNP) | VAF 52/500 reads (10%) | called by muse, mutect2
- NCF1 | c.574+112dup | Intron (INS) | VAF 34/331 reads (10%) | called by mutect2, pindel, varscan2
- ROGDI | c.117+292C>G | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2, varscan2
- SLC30A6 | c.284+2871C>T | Intron (SNP) | VAF 11/204 reads (5%) | catalogued as rs911981548; called by muse, mutect2
- TPRX2P | n.189C>T | RNA (SNP) | VAF 12/72 reads (17%) | catalogued as rs751002798; called by muse, varscan2
- TPRX2P | n.246C>T | RNA (SNP) | VAF 20/103 reads (19%) | catalogued as rs1209565862; called by muse, varscan2
- YJEFN3 | chr19:19528888 C>T | 5'Flank (SNP) | VAF 16/108 reads (15%) | catalogued as rs1479871097; called by muse, mutect2, varscan2
- ZNF655 | c.136+3220G>A | Intron (SNP) | VAF 28/354 reads (8%) | catalogued as rs777873750, COSV53160010; called by muse, mutect2
